Somatic mutation profile of tumor specimen TCGA-24-1103-01A (aliquot TCGA-24-1103-01A-01W-0488-09) from TCGA case TCGA-24-1103, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.9 years (18,583 days).
Specimen TCGA-24-1103-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7d47cd5-d7a1-4fc4-81d0-92b0c7fb7226.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1103-10A (Blood Derived Normal), aliquot TCGA-24-1103-10A-01W-0488-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cd59205-d8b4-447e-98b1-48b31b73ce2f

The open-access MAF lists 83 somatic variants for this specimen: 64 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 53, Silent 19, Splice Region 3, Splice Site 3, Frame Shift Del 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 160/177 reads (90%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AACS | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 209/399 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55540567; called by muse, mutect2, varscan2
- AASDH | c.1922G>T p.S641I | Missense Mutation (SNP) | VAF 147/327 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV52710843; called by muse, mutect2, varscan2
- AFDN | c.4303A>T p.R1435* | Nonsense Mutation (SNP) | VAF 58/70 reads (83%) | catalogued as COSV60057326; called by muse, mutect2, varscan2
- AGTPBP1 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 180/372 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as COSV61277582; called by muse, mutect2, varscan2
- ALDH1B1 | c.678G>C p.K226N | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100890875; called by muse, mutect2
- ALG8 | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 196/285 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200888240, COSV100219986, COSV55203161; called by muse, varscan2
- ANKAR | c.3538C>G p.L1180V | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs368191509; called by muse, mutect2, varscan2
- ATP1A1 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775243249, COSV55194340; called by muse, mutect2, varscan2
- BRCA2 | c.4912A>G p.K1638E | Missense Mutation (SNP) | VAF 81/88 reads (92%) | SIFT tolerated (0.38); PolyPhen benign (0.075); catalogued as rs886040553, COSV66462554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.2697C>A p.H899Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as COSV56527941; called by muse, mutect2, varscan2
- CHIA | c.915G>A p.E305= (on ENST00000343320; = p.E197= on NM_021797.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 97/225 reads (43%) | catalogued as COSV58475110, COSV58478402; called by muse, mutect2, varscan2
- CLPTM1 | c.408G>T p.W136C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61613197; called by muse, mutect2, varscan2
- DOCK11 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 374/758 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52247936; called by muse, mutect2, varscan2
- DPP10 | c.536T>A p.V179D | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.356); catalogued as COSV59729959; called by muse, mutect2, varscan2
- DPP8 | c.595-1G>A p.X199_splice (on ENST00000341861 / NM_001320875.2; = p.X183_splice on NM_017743.6) | Splice Site (SNP) | VAF 7/100 reads (7%) | catalogued as COSV100201997; called by muse, mutect2
- DRD3 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55683016; called by muse, mutect2, varscan2
- DZIP1L | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.107); catalogued as COSV59523600; called by muse, mutect2, varscan2
- EPHA2 | c.2736G>C p.W912C | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64454762; called by muse, mutect2, varscan2
- EVA1C | c.1205G>T p.S402I | Missense Mutation (SNP) | VAF 218/247 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.361); catalogued as COSV55827037; called by muse, mutect2, varscan2
- EXOC1 | c.2126T>G p.V709G | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62122070; called by muse, mutect2, varscan2
- F8 | c.5586G>T p.L1862= | Splice Region (SNP) | VAF 103/189 reads (54%) | catalogued as CS910427, COSV64278875; called by muse, mutect2, varscan2
- FAM83D | c.1428G>T p.K476N | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.107); catalogued as COSV54159286; called by muse, mutect2, varscan2
- FAT1 | c.469T>C p.S157P | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV71676094; called by muse, mutect2
- FOXJ2 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 114/254 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs1276608804, COSV50825035; called by muse, mutect2, varscan2
- GABRQ | c.875A>T p.D292V | Missense Mutation (SNP) | VAF 46/1122 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV100941053; called by muse, mutect2
- GALNT2 | c.968A>T p.K323M | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV64197616; called by muse, mutect2, varscan2
- HEATR1 | c.322A>C p.K108Q | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100857179; called by muse, mutect2
- HNRNPA3 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV66821203; called by muse, mutect2, varscan2
- KCNMA1 | c.638T>G p.F213C | Missense Mutation (SNP) | VAF 201/430 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as COSV54288830; called by muse, mutect2, varscan2
- KDM3B | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.596); catalogued as COSV100069025; called by muse, mutect2
- LRRC7 | c.4601C>A p.P1534H (on ENST00000651989 / NM_001370785.2; = p.P1454H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/66 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50633393; called by muse, mutect2, varscan2
- MAP2 | c.79C>G p.H27D | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV52308569; called by muse, mutect2, varscan2
- MKI67 | c.8866C>G p.L2956V | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.232); catalogued as COSV64077070; called by muse, mutect2, varscan2
- MX2 | c.441C>T p.S147= | Splice Region (SNP) | VAF 21/21 reads (100%) | catalogued as rs780402246, COSV58099747; called by muse, mutect2, varscan2
- NBEAL1 | c.4174G>C p.D1392H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as COSV101495587; called by muse, mutect2
- NEXMIF | c.4403A>G p.E1468G | Missense Mutation (SNP) | VAF 189/363 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV50029221; called by muse, mutect2, varscan2
- OR10H1 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.06); catalogued as COSV100612325; called by muse, mutect2
- OR5B21 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV64482284; called by muse, mutect2, varscan2
- PCDHGA12 | c.2684T>G p.V895G | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV52768786; called by muse, mutect2, varscan2
- PDE1A | c.1255+1G>A p.X419_splice | Splice Site (SNP) | VAF 18/482 reads (4%) | catalogued as COSV100112319, COSV59535274; called by muse, mutect2
- PDE8A | c.2237A>C p.E746A | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59640733; called by muse, mutect2, varscan2
- POLR2B | c.750T>A p.S250R | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.219); catalogued as COSV58902870; called by muse, mutect2, varscan2
- PRKD3 | c.448T>G p.F150V | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV52218839; called by muse, mutect2, varscan2
- PRLR | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 296/963 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV51500884; called by muse, mutect2, varscan2
- PRMT8 | c.740T>G p.M247R | Missense Mutation (SNP) | VAF 304/669 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV54219526; called by muse, mutect2, varscan2
- QRICH2 | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1209167432, COSV53157946; called by muse, mutect2, varscan2
- RASA2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759141778, COSV53937672; called by muse, mutect2, varscan2
- RIPK2 | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 96/438 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV55135124; called by muse, mutect2, varscan2
- SLC26A7 | c.368T>G p.M123R | Missense Mutation (SNP) | VAF 240/326 reads (74%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52604948; called by muse, mutect2, varscan2
- TRRAP | c.10345G>C p.E3449Q (on ENST00000359863 / NM_001244580.1; = p.E3420Q on NM_003496.3) | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV62854794; called by muse, mutect2, varscan2
- TXLNB | c.482A>G p.K161R | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1239214253, COSV100624772, COSV64445342; called by muse, mutect2
- TYR | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 34/619 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99632653; called by muse, mutect2
- UMODL1 | c.2293C>A p.H765N (on ENST00000408910 / NM_001004416.2; = p.H893N on NM_173568.3) | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV68578057; called by muse, mutect2, varscan2
- VAV3 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 176/418 reads (42%) | catalogued as COSV58392724; called by muse, mutect2, varscan2
- XIRP1 | c.3866A>T p.D1289V | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV61141461; called by muse, mutect2, varscan2
- ZBTB38 | c.3323C>A p.T1108N | Missense Mutation (SNP) | VAF 153/295 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58544366; called by muse, mutect2, varscan2
- ZBTB41 | c.2711C>G p.T904R | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV100962720; called by muse, mutect2
- ZNF197 | c.1725C>A p.F575L | Missense Mutation (SNP) | VAF 104/168 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV60362217; called by muse, mutect2, varscan2
- ZNF491 | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as COSV60058957; called by muse, mutect2, varscan2
- ZNF682 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV62068586; called by muse, mutect2, varscan2
- ZNF791 | c.1178_1179del p.F393* | Frame Shift Del (DEL) | VAF 126/332 reads (38%) | catalogued as COSV58482888; called by mutect2, pindel, varscan2
- OR2S2 | c.273_288del p.T92Pfs*20 | Frame Shift Del (DEL) | VAF 10/101 reads (10%) | called by mutect2, pindel
- ZFPM2 | c.2433_2440del p.S812* | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- ADSS2 | c.1083C>G p.T361= | Silent (SNP) | VAF 67/163 reads (41%) | catalogued as COSV63696293; called by muse, mutect2, varscan2
- AHNAK2 | c.15141T>G p.P5047= | Silent (SNP) | VAF 55/84 reads (65%) | catalogued as COSV60931385; called by muse, mutect2, varscan2
- ALDH1A1 | c.321G>A p.E107= | Silent (SNP) | VAF 111/231 reads (48%) | catalogued as rs765042365, COSV52794425; called by muse, mutect2, varscan2
- ANKS1B | c.1857T>A p.P619= | Silent (SNP) | VAF 23/526 reads (4%) | catalogued as COSV100241988; called by muse, mutect2
- BMP8B | c.792A>G p.A264= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV59594722; called by muse, varscan2
- DCBLD1 | c.690G>T p.G230= | Silent (SNP) | VAF 64/68 reads (94%) | catalogued as COSV51646482; called by muse, mutect2, varscan2
- DDC | c.552G>A p.V184= | Silent (SNP) | VAF 75/88 reads (85%) | catalogued as COSV63567950; called by muse, mutect2, varscan2
- ELOA2 | c.1587G>A p.L529= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV55308971; called by muse, mutect2, varscan2
- FAM135B | c.3777C>G p.T1259= | Silent (SNP) | VAF 270/359 reads (75%) | catalogued as rs747163573, COSV52722909; called by muse, mutect2, varscan2
- FAM83C | c.2139G>C p.L713= | Silent (SNP) | VAF 78/250 reads (31%) | catalogued as COSV65584560; called by muse, mutect2, varscan2
- FER1L6 | c.4773G>A p.R1591= | Silent (SNP) | VAF 152/631 reads (24%) | catalogued as rs751596489, COSV67552889; called by muse, mutect2, varscan2
- FNDC8 | c.900C>T p.P300= | Silent (SNP) | VAF 60/67 reads (90%) | catalogued as COSV50104803; called by muse, mutect2, varscan2
- GPBAR1 | c.738C>G p.L246= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV50309707; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.846C>G p.G282= (on ENST00000354667 / NM_031243.3; = p.G270= on NM_002137.4) | Silent (SNP) | VAF 101/111 reads (91%) | catalogued as COSV61161242; called by muse, mutect2, varscan2
- NDUFV2 | c.387G>A p.K129= | Silent (SNP) | VAF 13/199 reads (7%) | catalogued as COSV59188163; called by muse, mutect2
- NTRK1 | c.456T>C p.C152= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV62328706; called by muse, mutect2, varscan2
- RBAK | c.699T>C p.Y233= | Silent (SNP) | VAF 60/148 reads (41%) | catalogued as rs1232605986, COSV62332534; called by muse, mutect2, varscan2
- SPAG17 | c.6618A>G p.T2206= | Silent (SNP) | VAF 103/222 reads (46%) | catalogued as COSV60468818; called by muse, mutect2, varscan2
- TMC2 | c.1680C>A p.P560= | Silent (SNP) | VAF 130/249 reads (52%) | catalogued as COSV62658595; called by muse, mutect2, varscan2
